Somatic mutation profile of tumor specimen 0DAPMB from CCDI case PBBKEA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, benign; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,460 days).
Specimen 0DAPMB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f373343-4de5-4796-a2c6-9b00e6ffb160.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAPM8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c47881b-453a-413c-ba39-60a5e88a29b5

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDZRN4 | c.2350G>A p.G784R (on ENST00000402685 / NM_001164595.2; = p.G526R on NM_013377.4) | Missense Mutation (SNP) | VAF 163/638 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV54203810; called by muse, mutect2, varscan2
- RAPGEF5 | c.664C>T p.H222Y (on ENST00000401957 / NM_001367602.2; = p.H525Y on NM_012294.5) | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs746684694; called by muse, mutect2, varscan2
- CTNNA2 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 12/400 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- MYH3 | c.2630A>G p.K877R | Missense Mutation (SNP) | VAF 101/521 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- PRB2 | c.65A>G p.D22G | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.136); called by muse, mutect2
